Somatic mutation profile of tumor specimen 0DC2A3 from CCDI case PBBLLP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal sarcoma; Tissue or organ of origin: Liver; Age at diagnosis: 11.9 years (4,340 days).
Specimen 0DC2A3: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d69c1cf2-590e-4426-8126-68b8d9c95f21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC29O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1718f4d-a176-450c-a1c5-3b9260fbac32

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 121/232 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CPQ | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 116/348 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776649168; called by muse, mutect2, varscan2
- ZNF611 | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs778257387; called by muse, mutect2, varscan2
- CAPN10 | c.1726G>C p.G576R | Missense Mutation (SNP) | VAF 214/652 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX14 | c.92del p.S31Mfs*80 | Frame Shift Del (DEL) | VAF 104/331 reads (31%) | called by mutect2, pindel, varscan2
- GCNT2 | c.60dup p.V21Cfs*7 | Frame Shift Ins (INS) | VAF 99/257 reads (39%) | called by mutect2, pindel, varscan2
- LRCH2 | c.201C>G p.N67K | Missense Mutation (SNP) | VAF 160/605 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PI4KA | c.5671C>G p.P1891A | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- UQCRFS1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 161/2278 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2
- CKAP5 | c.5026C>T p.L1676= (on ENST00000529230 / NM_001008938.4; = p.L1616= on NM_014756.3) | Silent (SNP) | VAF 35/300 reads (12%) | called by muse, mutect2, varscan2
- MME | c.877C>A p.R293= | Silent (SNP) | VAF 90/265 reads (34%) | catalogued as COSV64706012, COSV64706568, COSV64710641; called by muse, mutect2, varscan2
- SRCAP | c.9633C>T p.S3211= | Silent (SNP) | VAF 84/359 reads (23%) | catalogued as rs78465857, COSV99349968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNIP2 | c.*32A>G | 3'UTR (SNP) | VAF 96/248 reads (39%) | called by muse, mutect2, varscan2
- SPRR3 | c.*82T>C | 3'UTR (SNP) | VAF 24/83 reads (29%) | called by muse, varscan2
